Somatic mutation profile of tumor specimen MP2PRT-PASIIA-TMP1-A (aliquot MP2PRT-PASIIA-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PASIIA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,794 days).
Specimen MP2PRT-PASIIA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54708be3-99a7-489e-a225-92ba77bb93ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASIIA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASIIA-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c158cb08-898b-4769-ad48-9c25a8835d3d

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Ins 1, 5'Flank 1, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf54 | c.3796G>C p.E1266Q | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as rs778159331; called by muse, mutect2, varscan2
- GRID1 | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 246/553 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as rs774434941, COSV60020654, COSV60052140; called by muse, mutect2, varscan2
- ITPR1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 15/531 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797044955, CM1311263, CM154818, COSV56989747; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2
- JAKMIP1 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 252/558 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557871910, COSV101290894; called by muse, mutect2, varscan2
- KIF1A | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 226/500 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs764578297; called by muse, varscan2
- LAMB1 | c.3037C>T p.R1013W | Missense Mutation (SNP) | VAF 150/367 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs767303427; called by muse, mutect2, varscan2
- MFHAS1 | c.2555G>T p.C852F | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.113); catalogued as rs1057291054; called by muse, mutect2, varscan2
- AVPR1B | c.118_119insCC p.V40Afs*19 | Frame Shift Ins (INS) | VAF 224/560 reads (40%) | called by mutect2, pindel, varscan2
- CACNA1E | c.4544T>C p.I1515T | Missense Mutation (SNP) | VAF 184/386 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- DBNDD2 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 285/657 reads (43%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IGLV4-69 | c.355_357del p.I119del | In Frame Del (DEL) | VAF 44/158 reads (28%) | called by pindel*, varscan2
- KRT82 | c.482G>T p.C161F | Missense Mutation (SNP) | VAF 146/580 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- PLEKHH1 | c.3605C>A p.T1202K | Missense Mutation (SNP) | VAF 91/391 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPFIA2 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RNF123 | c.1758C>A p.Y586* | Nonsense Mutation (SNP) | VAF 48/337 reads (14%) | called by muse, mutect2, varscan2
- TRGV3 | c.352del p.R118del | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2*, pindel*, varscan2
- BAIAP2 | c.1035G>A p.K345= | Silent (SNP) | VAF 175/419 reads (42%) | catalogued as rs769137567; called by muse, varscan2
- ELOA3 | c.912G>A p.A304= | Silent (SNP) | VAF 262/3208 reads (8%) | catalogued as rs1334210983, COSV99796114; called by muse, mutect2
- GP6 | c.915G>C p.V305= | Silent (SNP) | VAF 300/706 reads (42%) | catalogued as COSV59977134; called by muse, mutect2
- CD28 | chr2:203706596 G>T | 5'Flank (SNP) | VAF 228/539 reads (42%) | catalogued as COSV60730245; called by muse, mutect2, varscan2
